Gene-level copy-number profile of tumor specimen TCGA-24-1416-01A from TCGA case TCGA-24-1416, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 35.0 years (12,772 days).
Specimen TCGA-24-1416-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3037de81-f2ec-4f7c-ad35-649743bfdb2f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1416-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dec9f1a9-5807-43ce-82e5-3e4e9b815354

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 7,091; copy number 3: 5,091; copy number 4: 3,737; copy number 5: 532; copy number 6: 40,107; copy number 7: 11; copy number 8: 58; copy number 9: 2,213; copy number 12: 368; copy number 13: 138; copy number 15: 290; copy number 17: 180.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1416-01A-01D-0472-01): tumor purity 0.82, ploidy 3.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 608 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,221,126–74,794,523, 318 genes, copy number 13–17 (broad region; genes not listed).
- chr19:10,486,125–15,498,956, 289 genes, copy number 15 (within-gene range 3–15) (broad region; genes not listed).
- chr19:15,515,342–15,516,836, 1 gene, copy number 15: AC011492.1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
